Surgical pathology report (de-identified scan), TCGA case TCGA-4W-AA9S, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Miami, specimen TCGA-4W-AA9S-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:

PAGE 1

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED] #: [REDACTED]
AGE/SEX: /M DOB: [REDACTED] ROOM: [REDACTED] REG: [REDACTED]
REG DR: [REDACTED] STATUS: [REDACTED] BED: [REDACTED] DIS: [REDACTED]

Path #: [REDACTED] Received: [REDACTED] Collect d: [REDACTED]
Submit Dr: [REDACTED] Copies to: [REDACTED]

SPECIMEN ID:

A. BRAIN - LEFT BRAIN TUMOR FS, B. BRAIN - LEFT BRAIN TUMOR

*** FINAL DIAGNOSTIC ***

A. LEFT BRAIN TUMOR FROZEN SECTION:

Glioblastoma (GBM, astrocytoma, grade IV).

B. LEFT BRAIN TUMOR:

Glioblastoma (GBM, astrocytoma, grade IV).

Dictated by: [REDACTED]

ICD O-3
Glioblastoma multiforme
9440/3
Site @ Brain NOS
C71.9
JW 3/11/14

CLINICAL HISTORY-

PRE-OP DX: None provided

PROCEDURE: Left frontotemporal brain tumor

RELEVANT CLINICAL HX: Brain tumor

GROSS DESCRIPTION:

- A. Received fresh labeled as "left brain tumor frozen section" are two irregularly shaped pink tan soft tissue fragments measuring in aggregate 0.4 x 0.4 x 0.2 cm. The specimen is submitted in toto in one cassette for frozen section.
- B. Received in formalin labeled as "left brain tumor" are multiple irregularly shaped soft friable---> focally hemorrhagic tissue fragments measuring in aggregate 4.5 x 3.5 x 2 cm. On section reveal a pink white soft cut surface with extensive necrosis.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 2 of 2]
RUN DATE:
RUN TIME:

PAGE 2

SPEC #: [REDACTED]

(Continued)

GROSS DESCRIPTION: (Continued)

Representative sections are submitted in four cassettes.

OPERATING ROOM CONSULT (FS-CYT)

AFS: LEFT BRAIN TUMOR:

Necrotic tumor. The small amount of viable tissue is consistent with an astrocytic origin of the tumor.

Dictated by: [REDACTED]

Signed _____

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

Source: NCI Genomic Data Commons file 3dd293c2-458e-40bb-b087-81069e916b2f (TCGA-4W-AA9S.87CEFA2B-7AA8-40DA-A987-9050F449D828.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).